Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A2QK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A2QK-01A (Primary Tumor).

[page 1 of 2]
Sex: Female
D.O.B.:
MRN #:
Ref Phy:

SPECIMEN INFORMATION

Collected: Accession
Received: Acct / Reg #
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Omentum, biopsy:
Tumor not identified.
- B. Left paraaortic lymph nodes, excision:
Two lymph nodes, negative for metastatic disease.
Frozen section diagnosis confirmed.
- C. Left paraaortic lymph nodes, excision:
Three lymph nodes, negative for metastatic disease.
- D. Right paraaortic lymph nodes, excision:
Three lymph nodes, negative for metastatic disease.
- E. Left pelvic lymph nodes, excision:
Ten lymph nodes, negative for metastatic disease.
- F. Right pelvic lymph nodes, excision:
Eight lymph nodes, negative for metastatic disease.
- G. Uterus, bilateral adnexa, hysterectomy with bilateral salpingoophorectomy:
Cervix:
Tumor Characteristics:
1. Histologic type: Endometrioid adenocarcinoma.
2. Histologic grade: 3.
3. Tumor site: Endometrium.
4. Tumor size: 5.0 x 2.7 cm.
5. Myometrial invasion: Tumor extends 0.7 cm into a 2.8 cm thick myometrium.
6. Involvement of cervix: Not seen.
7. Extent of involvement of other organs: Not identified.
8. Lymphovascular space invasion: Focally present.
Surgical Margin Status:
1. Margins uninvolved: Cervix, serosa, parametria.
2. Margins involved: None.
Lymph Node Status:
Number of lymph nodes received: See above.
Other:
1. Other significant findings:
a. Myometrium leiomyomata.
b. Attached ovary with focus of stromal hyperthecosis.
c. Separate ovary and bilateral fallopian tubes without evidence of malignancy.
2. pTNM stage: pT1aN0 (FIGO IA).

Dual/Syncronous Primary Noted		X

ICD-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium C54.1
pw
9/3/11

Electronic Signature:

COMMENTS:

Appropriately controlled immunochemical stains performed on blocks G3 show the following results:

P53 - Focally positive in lesional cells.
WT-1 - Negative in lesional cells.
Cytokeratin 7 - Positive in lesional cells.
Cytokeratin 20 - Negative in lesional cells.
CDX2 - Negative in lesional cells.
Inhibin - Negative in lesional cells.

[page 2 of 2]
Additional controlled immunostains were performed on block G16 with the following results:

Cytokeratin 7 - Negative in cellular proliferation.
Cytokeratin 20 - Negative in cellular proliferation.
CDX2 - Negative in cellular proliferation.
P53 - Negative in cellular proliferation.
WT-1 - Negative in cellular proliferation.
Inhibin - Positive in cellular proliferation.

Findings consistent with stromal hyperthecosis.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Omentum biopsy
- B. Left paraaortic lymph nodes
- C. Left paraaortic lymph nodes
- D. Right paraaortic lymph nodes
- E. Left pelvic lymph nodes
- F. Right pelvic lymph nodes
- G. Uterus, cervix, bilateral tubes and ovaries

SPECIMEN DATA

GROSS DESCRIPTION:

A. The first container A is labeled omentum biopsy. The specimen consists of a piece of yellow tan fibroadipose tissue measuring 1.5 x 1.0 x 0.5 cm. The specimen is bisected. There are no nodules grossly identified. The specimen is entirely submitted in a single cassette

B. The second container B is labeled left paraaortic lymph nodes #2. The specimen consists of two probable lymph nodes measuring 1.0 x 1.0 x 0.5 cm and 1.5 x 1.2 x 0.5 cm. The smaller piece has been inked. Each of the lymph nodes have been bisected. The lymph nodes are entirely submitted in cassette

C. The third container C is labeled left paraaortic lymph node. The specimen consists of a portion of fibroadipose tissue measuring 6.0 x 3.5 x 1.0 cm. Sectioning reveals three probable lymph nodes measuring from 0.5 to 1.8 cm. The lymph nodes are entirely submitted in cassettes as follows: one probable node bisected-1; one probable node bisected-2; one probable node-3.

D. The fourth container D is labeled right paraaortic. The specimen consists of a portion of fibroadipose tissue measuring 5.0 x 4.0 x 1.5 cm. Sectioning reveals three probable lymph nodes measuring from 0.7 to 3.0 cm in greatest dimension. The lymph nodes are entirely submitted in cassettes as follows: two probable nodes-1; one probable node sectioned-2 to 5.

E. The fifth container E is labeled left pelvic lymph nodes. The specimen consists of a portion of fibroadipose tissue measuring 11.0 x 7.0 x 3.0 cm. Sectioning reveals eleven probable lymph nodes measuring from 0.7 up to 2.5 cm. The lymph nodes are entirely submitted in cassettes as follows: one probable node bisected-1; two probable nodes-2; one probable node bisected-3 and 4; one probable lymph node bisected-5 and 6; one probable lymph node bisected-7 and 8; one probable lymph node bisected-9; one probable lymph node bisected-10; one probable lymph node bisected-11 and 12; one probable lymph node bisected-13 and 14.

F. The sixth container F is labeled right pelvic lymph nodes. The specimen consists of a portion of fibroadipose tissue measuring 10.0 x 7.5 x 4.0 cm. Sectioning reveals seven probable lymph nodes measuring from 0.9 up to 4.2 cm. The lymph nodes are entirely submitted, with the exception of the largest lymph node, in cassettes as follows: one probable lymph node bisected-1; one probable lymph node bisected-2; one probable lymph node bisected-3; two probable lymph nodes-4; one probable lymph node-5; one probable lymph node sectioned-6 to 9; representative sections from the largest lymph node-10 to 13.

G. The seventh container G is labeled uterus, cervix, bilateral tubes and ovaries. The specimen consists of a previously bisected uterus with attached cervix, attached left adnexa and separately submitted right adnexa. The serosal surface of the uterus is gray to brown tan with slight hemorrhage and adhesions. The serosa has been inked. Sections from the parametrium have been taken. The cervix measures 4.5 cm in length and 3.5 cm in diameter. The ectocervix is gray to brown tan with hemorrhage. The endocervical canal is light tan and reveals normal mucosal folds. There are no masses identified. The endometrial cavity measures 6.0 cm in length and 4.0 cm in diameter. The lining is gray to brown tan and

hemorrhagic revealing a brown tan shaggy polypoid mass measuring 5.0 x 2.7 cm that is within 2.1 cm of the lower uterine segment. On sectioning the mass extends into the underlying myometrium approximately 0.7 cm into a 2.8 cm myometrium. The myometrium is gray tan trabecular. There are white tan whorled intramural masses identified measuring up to 0.9 cm. On sectioning there is no evidence of hemorrhage or necrosis. The attached ovary measures 3.0 x 2.0 x 1.0 cm. The surface is gray tan cribriform. On sectioning the cut surface is yellow to gray tan displaying corpus albicans measuring up to 0.5 cm. The corresponding fallopian tube measures 3.0 cm in length and 0.3 cm in diameter. The surface is gray to brown tan. On sectioning the fallopian tube appears grossly unremarkable. The separately submitted ovary measures 4.0 x 1.5 x 0.5 cm. The surface is gray tan cribriform. On sectioning the cut surface is yellow to gray tan. There are corpus albicans measuring up to 0.5 cm identified. The corresponding fallopian tube measures 8.0 cm in length and 1.0 cm in diameter. The surface is gray to brown tan. On sectioning the lumen is dilated measuring up to 0.7 cm containing serosanguineous fluid. No other lesions are identified. Received with the specimen are three cassettes, one green, one blue, one yellow, labeled The yellow one is additionally labeled 16, green one additionally labeled 17, and the blue one additionally labeled 18. Representative sections are submitted in cassettes as follows: anterior cervix-1; posterior cervix-2; full thickness sections from the mass bisected as follows: one cross section-3 and 4; one cross section-5 and 6; one cross section-7 and 8; one cross section-9 and 10; polypoid portion of the mass-11; lower uterine segment-12; left parametrium-13; right parametrium-14; sections from the myometrial masses-15; attached ovary-16; corresponding tube-17; separately submitted ovary-18; corresponding tube-19.

Source: NCI Genomic Data Commons file dc55fecc-849e-4619-96f1-083ecbae6210 (TCGA-AJ-A2QK.01A114A2-098F-4AAD-9010-54910FB89B4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).